Somatic mutation profile of tumor specimen C3N-02186-03 (aliquot CPT0168720006) from CPTAC case C3N-02186, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.5 years (19,526 days).
Specimen C3N-02186-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3c11e6c-22b2-4c73-8bdf-241441d99131.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02186-71 (Blood Derived Normal), aliquot CPT0168760004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e8881db-a343-4f51-9a60-64629c6e287d

The open-access MAF lists 81 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Nonsense Mutation 6, Intron 6, Frame Shift Del 3, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs779937883, COSV100719479; called by muse, mutect2, varscan2
- ATP8A1 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 59/206 reads (29%) | catalogued as COSV52542296; called by muse, mutect2, varscan2
- C15orf39 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1472286889; called by muse, mutect2, varscan2
- C3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 132/478 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765821415, COSV55568720; called by muse, mutect2, varscan2
- CCN6 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs782703789, COSV100037059; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD96 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 27/325 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs372467879, COSV99342940; called by muse, mutect2
- CDH18 | c.2057A>T p.K686M | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV56960342; called by muse, mutect2, varscan2
- DNASE1L2 | c.689G>A p.W230* | Nonsense Mutation (SNP) | VAF 104/329 reads (32%) | catalogued as rs776621988; called by muse, mutect2, varscan2
- EGFR | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 72/2600 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV51778955, COSV51820698; called by muse, mutect2
- FSIP2 | c.18601_18604del p.R6201Qfs*4 | Frame Shift Del (DEL) | VAF 44/131 reads (34%) | catalogued as rs764423764; called by pindel, varscan2
- GALNT9 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782268070, COSV61096285; called by muse, mutect2
- IRAG2 | c.3944G>A p.R1315H (on ENST00000636465; = p.R360H on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147775174; called by muse, mutect2, varscan2
- NLRC3 | c.3023A>G p.N1008S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs760942910; called by muse, mutect2, varscan2
- TMPRSS4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs748384003, COSV71108660; called by muse, mutect2
- TRPC6 | c.1766C>G p.S589C | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs878853193; ClinVar: drug response; called by muse, mutect2, varscan2
- TTN | c.28906G>A p.G9636S (on ENST00000591111; = p.G8709S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | PolyPhen probably damaging (0.979); catalogued as rs770212603; ClinVar: uncertain significance; called by muse, mutect2
- WDR24 | c.2453G>A p.R818H (on ENST00000248142; = p.R688H on NM_032259.4) | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs1207926430; called by muse, mutect2, varscan2
- ANK3 | c.7375G>T p.E2459* | Nonsense Mutation (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- APIP | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- C19orf71 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 87/213 reads (41%) | called by muse, mutect2, varscan2
- CLPP | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- DAB2 | c.1658_1663del p.S553_G554del | In Frame Del (DEL) | VAF 44/259 reads (17%) | called by mutect2, pindel, varscan2
- DDX28 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- DIO3 | c.318C>A p.N106K | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- EIF3B | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- EYA3 | c.71C>G p.T24S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGRT | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- FLG2 | c.3281C>G p.S1094* | Nonsense Mutation (SNP) | VAF 124/426 reads (29%) | called by muse, mutect2, varscan2
- GAS1 | c.948G>C p.R316S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- HEXA | c.87del p.F30Sfs*70 | Frame Shift Del (DEL) | VAF 115/434 reads (26%) | called by mutect2, pindel, varscan2
- HGD | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2
- IFT22 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- IGKV3-11 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- ITPR1 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYPD3 | c.935A>G p.Y312C | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- MAP3K1 | c.1338C>G p.C446W | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSLN | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.045); called by muse, mutect2
- MSR1 | c.1331A>T p.D444V | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSMF | c.1060A>G p.K354E (on ENST00000371475 / NM_001130969.3; = p.K352E on NM_015537.4) | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ODAPH | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 152/554 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- OPN1SW | c.983A>G p.D328G | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2
- OR4C11 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- OR5F1 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PASD1 | c.1908G>C p.E636D | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0.058); called by muse, mutect2
- PCDHGA12 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2
- PHF3 | c.3531G>C p.E1177D | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, varscan2
- PKHD1 | c.10146del p.F3383Sfs*17 | Frame Shift Del (DEL) | VAF 49/240 reads (20%) | called by mutect2, pindel, varscan2
- PON1 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2, varscan2
- RSF1 | c.2099C>G p.S700C | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SOWAHD | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SOWAHD | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STAU2 | c.589G>T p.D197Y (on ENST00000524300 / NM_001164380.2; = p.D165Y on NM_014393.2) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TACC2 | c.7541C>A p.T2514N (on ENST00000334433; = p.T592N on NM_006997.4) | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- UBTFL1 | c.1012G>T p.G338W | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- UGT8 | c.200A>T p.H67L | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.103); called by muse, mutect2
- ZNF212 | c.1173C>A p.H391Q | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ABCB1 | c.1695C>T p.S565= | Silent (SNP) | VAF 46/368 reads (13%) | catalogued as rs59697741, COSV99714337; called by muse, mutect2, varscan2
- ADCY5 | c.279C>T p.F93= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as rs1258380765; called by muse, mutect2
- ARC | c.138C>T p.H46= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1252647581; called by muse, mutect2, varscan2
- CBFA2T3 | c.1893C>T p.A631= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1352210531; called by muse, mutect2
- CILP2 | c.2550C>T p.D850= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs1568370469, COSV52274992; called by muse, mutect2, varscan2
- DENND3 | c.648C>T p.I216= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as rs373705581; called by muse, mutect2, varscan2
- FRRS1 | c.1170G>A p.L390= | Silent (SNP) | VAF 54/220 reads (25%) | called by muse, mutect2, varscan2
- HEPHL1 | c.1692C>T p.G564= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs1293721982, COSV59894463; called by muse, mutect2, varscan2
- IRS2 | c.3039G>A p.P1013= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs751368642; called by muse, mutect2, varscan2
- MUC16 | c.29202T>A p.P9734= | Silent (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- NLRP4 | c.2388C>T p.C796= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as rs150841636; called by muse, mutect2, varscan2
- PCLO | c.5082C>T p.D1694= | Silent (SNP) | VAF 47/197 reads (24%) | catalogued as rs367988765, COSV100436349; called by muse, mutect2, varscan2
- SULF1 | c.657C>T p.I219= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV99484582; called by muse, mutect2, varscan2
- TFEC | c.129A>G p.K43= | Silent (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- TTLL5 | c.1698A>G p.P566= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.36645C>T p.N12215= (on ENST00000591111; = p.N4791= on NM_003319.4) | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs559906667, COSV100601664; ClinVar: likely benign; called by muse, mutect2
- ZNF536 | c.924G>A p.A308= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1391148102; called by muse, mutect2, varscan2
- AC112715.1 | n.197G>A | RNA (SNP) | VAF 35/99 reads (35%) | catalogued as rs766016975; called by muse, mutect2, varscan2
- ARFGAP1 | c.835-185C>A | Intron (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.1524-19dup | Intron (INS) | VAF 47/173 reads (27%) | called by mutect2, pindel, varscan2
- DEFB121 | n.170C>A | RNA (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2
- SH3GL3 | c.187+96G>A | Intron (SNP) | VAF 18/92 reads (20%) | catalogued as rs754796115; called by muse, mutect2, varscan2
- STRAP | c.112+287C>A | Intron (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- UGT1A6 | c.862-23166C>T | Intron (SNP) | VAF 24/160 reads (15%) | catalogued as rs1183331531; called by muse, mutect2
- ZNF783 | c.802+3802A>G | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
